Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A01J, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A01J-01A (Primary Tumor).

Sample ID #

Diagnosis:

1. Mildly fibrosing cholecystitis, with clinically indicated cholecystolithiasis.
2. Resected rectosigmoidal material with an ulcerated, moderately differentiated adenocarcinoma of the colorectal type, located 1 cm from the aboral resection margin and measuring 2.5 cm in diameter, with infiltration of the pericolic fatty tissue. Tumor-free circumferential resection margin (distance between the tumor and the circumferential resection margin is 2.4 cm). Tumor-free colon resection margins. Tumor-free mesocolic resection margin.

Stage of tumor: pT3 pN0 (0/23) pMX; G2, L0, V0, R0.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site Rectum C20.9 w 3/31/11

Source: NCI Genomic Data Commons file bdf4bf6b-b12d-4785-8311-85b899aff4b5 (TCGA-AG-A01J.67030584-9883-4915-81ED-23F1937D3FE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).